Gene-level copy-number profile of tumor specimen TCGA-RY-A845-01A from TCGA case TCGA-RY-A845, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.0 years (14,617 days).
Specimen TCGA-RY-A845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.8a0329b3-9d2f-4a89-8977-07e20fa65a0b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RY-A845-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f060126-2d1f-491b-8af5-1910c7b944d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 41; copy number 2: 56,765; copy number 3: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RY-A845-01A-11D-A36N-01): tumor purity 0.83, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
